Gene-level copy-number profile of tumor specimen TCGA-2H-A9GO-01A from TCGA case TCGA-2H-A9GO, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 58.8 years (21,486 days).
Specimen TCGA-2H-A9GO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.6f7c9a09-b251-4785-a13b-795e6ebff40a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2H-A9GO-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b195e2a9-9bb3-41ad-add2-bd9546be722c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 476; copy number 2: 2,267; copy number 3: 8,944; copy number 4: 18,033; copy number 5: 13,665; copy number 6: 6,795; copy number 7: 3,777; copy number 8: 2,502; copy number 9: 1,307; copy number 10: 1,182; copy number 12: 226; copy number 13: 5; copy number 15: 115; copy number 16: 202; copy number 17: 76; copy number 19: 20; copy number 20: 47; copy number 21: 35; copy number 24: 16; copy number 25: 36; copy number 41: 16; copy number 44: 8; copy number 53: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2H-A9GO-01A-11D-A37B-01): tumor purity 0.56, ploidy 1.55, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:158,623,188–158,704,804, 2 genes: THAP5P1, NCAPG2.
- chr18:7,076,817–7,461,135, 5 genes: AP005062.1, SLC25A51P2, LRRC30, AP005270.1, AP001095.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,344 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:111,611,639–117,027,024, 103 genes, copy number 9–15 (within-gene range 8–15) (broad region; genes not listed).
- chr3:29,526,251–34,873,854, 72 genes, copy number 9–12 (broad region; genes not listed).
- chr3:36,712,422–42,683,793, 139 genes, copy number 10–12 (within-gene range 5–12) (broad region; genes not listed).
- chr3:175,369,540–198,222,513, 494 genes, copy number 10 (broad region; genes not listed).
- chr5:37,379,285–37,753,435, 1 gene, copy number 13 (within-gene range 5–16): WDR70.
- chr5:37,619,985–45,895,970, 130 genes, copy number 16–21 (broad region; genes not listed).
- chr6:60,719,222–61,241,311, 6 genes, copy number 9: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1.
- chr7:70,972–40,134,622, 723 genes, copy number 9–10 (broad region; genes not listed).
- chr7:40,151,613–40,154,151, 1 gene, copy number 9: THUMPD3P1.
- chr7:88,639,014–104,907,232, 382 genes, copy number 9–25 (within-gene range 6–25) (broad region; genes not listed).
- chr8:10,896,045–12,034,612, 47 genes, copy number 53: XKR6, MIR598, AF131215.3, AF131215.6, AF131215.5, AF131215.4, AF131215.2, AF131215.1, AF131215.7, LINC00529, RPL19P13, AF131216.2, AF131216.4, MTMR9, AF131216.1, SLC35G5, TDH, AF131216.3, FAM167A-AS1, RN7SL293P, RNU6-1084P, FAM167A, AF131216.5, BLK, AC022239.1, LINC00208, AC022239.2, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1, OR7E158P, OR7E161P, AC107918.5, AC107918.6, DEFB136, DEFB135, DEFB134, AC107918.3, DEFB131E, AC107918.4, AC107918.2, AC107918.1.
- chr8:12,945,642–13,031,503, 1 gene, copy number 53 (within-gene range 8–53): TRMT9B.
- chr8:13,044,350–15,238,431, 22 genes, copy number 41–53 (within-gene range 6–53): RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022832.2, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1, SGCZ, AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1.
- chr8:32,647,202–33,338,966, 8 genes, copy number 44: AC083977.1, RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9, AC104027.1, RNU6-528P.
- chr8:38,844,866–40,520,158, 30 genes, copy number 9: AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1.
- chr8:78,148,101–81,284,777, 62 genes, copy number 9 (broad region; genes not listed).
- chr10:44,259,602–53,458,288, 197 genes, copy number 9–20 (broad region; genes not listed).
- chr19:32,830,509–32,869,767, 1 gene, copy number 10 (within-gene range 8–10): SLC7A9.
- chr19:32,862,800–34,093,310, 34 genes, copy number 10: RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131, CHST8, KCTD15, AC008556.1, RN7SL150P, AC016587.1, RPS4XP23, RPS4XP20, RPS4XP21.
- chr20:30,484,925–64,313,132, 891 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 476. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
